Somatic mutation profile of tumor specimen TCGA-E8-A415-01A (aliquot TCGA-E8-A415-01A-11D-A23M-08) from TCGA case TCGA-E8-A415, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.1 years (14,288 days).
Specimen TCGA-E8-A415-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c08eb87-fc56-4cbd-b5f7-c2257a901828.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A415-10A (Blood Derived Normal), aliquot TCGA-E8-A415-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fce6b619-5d1c-41dc-9c45-209ea7052bed

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- NLRC4 | c.734T>C p.F245S | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61591308; called by muse, mutect2, varscan2
- NPSR1 | c.53C>T p.T18M | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs149663215; called by muse, mutect2, varscan2
- UBQLN2 | c.1717C>T p.P573S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV57739004; called by muse, mutect2, varscan2
